Somatic mutation profile of tumor specimen TCGA-UZ-A9PO-01A (aliquot TCGA-UZ-A9PO-01A-11D-A382-10) from TCGA case TCGA-UZ-A9PO, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-UZ-A9PO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8df78775-1a3c-4b78-8598-e51a0f2d7d7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PO-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PO-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66163ccd-f4a5-4dae-ad93-5242376ecf55

The open-access MAF lists 100 somatic variants for this specimen: 80 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 19, Frame Shift Del 8, Nonsense Mutation 3, Splice Site 3, In Frame Del 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS2 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55118024; called by muse, mutect2, varscan2
- ADAM11 | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52350508, COSV99567428; called by muse, mutect2
- ANXA7 | c.661C>A p.Q221K (on ENST00000372919 / NM_001320880.2; = p.Q199K on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV100873431; called by muse, mutect2, varscan2
- ATG4B | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV99994771; called by muse, mutect2, varscan2
- ATG4D | c.1187G>A p.G396D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100470055; called by muse, mutect2, varscan2
- BICDL1 | c.1697T>C p.L566P | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99984577; called by muse, mutect2, varscan2
- BOD1L1 | c.5294A>G p.N1765S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV99239196; called by muse, mutect2, varscan2
- C15orf39 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.212); catalogued as rs746156594, COSV100641311; called by muse, mutect2
- CASR | c.275C>A p.T92K | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV56133705, COSV99948869; called by muse, mutect2, varscan2
- CASS4 | c.1788G>C p.E596D | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.136); catalogued as rs1568682661, COSV100824655; called by muse, mutect2, varscan2
- CCDC18 | c.851A>G p.N284S | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV100159486; called by muse, mutect2, varscan2
- CDK19 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs760899404, COSV60447076, COSV60448991; called by muse, mutect2, varscan2
- CFAP20DC | c.2119G>A p.V707I (on ENST00000482387 / NM_001351530.2; = p.V456I on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as COSV99918585; called by muse, mutect2, varscan2
- CMC1 | c.247A>G p.K83E | Missense Mutation (SNP) | VAF 99/332 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.082); catalogued as COSV99843583; called by muse, mutect2, varscan2
- COLGALT1 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV99395011; called by muse, mutect2, varscan2
- CTCFL | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99712521; called by muse, mutect2, varscan2
- CYP4A11 | c.263A>G p.H88R | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100152349; called by muse, mutect2, varscan2
- DNAJA1 | c.310+2T>G p.X104_splice | Splice Site (SNP) | VAF 18/309 reads (6%) | catalogued as COSV100438477; called by muse, mutect2
- DOCK6 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs546562962, COSV53915240, COSV53923608; called by muse, mutect2, varscan2
- DOLK | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs377658203, COSV100454971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPB41L3 | c.3115A>G p.I1039V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59443204; called by muse, mutect2, varscan2
- ERAP1 | c.840T>A p.D280E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV99700877; called by muse, mutect2, varscan2
- ERN2 | c.1394C>T p.T465I | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV56831286, COSV99891386; called by muse, mutect2, varscan2
- FBLN2 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV99851802; called by muse, mutect2, varscan2
- FRY | c.6617A>G p.N2206S | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as rs773573210, COSV100969153; called by muse, mutect2, varscan2
- FSTL5 | c.2182C>A p.Q728K | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100054719; called by muse, mutect2, varscan2
- GPATCH1 | c.1238T>G p.L413R | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99403974; called by muse, mutect2, varscan2
- GTF3C4 | c.238G>C p.V80L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV100140041; called by muse, mutect2, varscan2
- IHH | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99838677; called by muse, mutect2, varscan2
- JSRP1 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs566252055, COSV99678332; called by muse, mutect2, varscan2
- KCTD17 | c.912G>C p.E304D (on ENST00000403888 / NM_001282684.1; = p.E280D on NM_024681.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100695699; called by muse, varscan2
- KCTD17 | c.913G>T p.A305S (on ENST00000403888 / NM_001282684.1; = p.A281S on NM_024681.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); catalogued as COSV100695701; called by muse, varscan2
- KDSR | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.761); catalogued as COSV100430228, COSV58508385; called by muse, mutect2, varscan2
- LPIN2 | c.1411C>G p.L471V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99858298; called by muse, mutect2, varscan2
- MAGED2 | c.1576T>G p.W526G | Missense Mutation (SNP) | VAF 97/153 reads (63%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.852); catalogued as COSV99514536; called by muse, mutect2, varscan2
- MAGEF1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.239); catalogued as rs994093983, COSV100510956; called by muse, mutect2, varscan2
- MBTPS1 | c.391A>C p.K131Q | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100597554; called by muse, mutect2, varscan2
- MEGF8 | c.6562G>A p.D2188N (on ENST00000251268 / NM_001271938.2; = p.D2121N on NM_001410.3) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as rs374088709, COSV99235876; called by muse, mutect2, varscan2
- MGAT5B | c.1982T>C p.F661S (on ENST00000569840 / NM_001199172.2; = p.F659S on NM_144677.3) | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100047894; called by muse, mutect2, varscan2
- MXD3 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs1259185023, COSV100293561; called by muse, mutect2, varscan2
- MYH1 | c.4557G>T p.Q1519H | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as COSV56850080, COSV99875714; called by muse, mutect2, varscan2
- MYSM1 | c.2179T>C p.F727L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV101284040; called by muse, mutect2, varscan2
- OLFML2B | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV99668357; called by muse, mutect2, varscan2
- PABPC4 | c.1009T>G p.F337V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100790872; called by muse, mutect2, varscan2
- PCDHB8 | c.1556C>G p.S519W | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV50759783, COSV50767627, COSV99176886; called by muse, mutect2, varscan2
- PCDHGA3 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV99536823; called by muse, mutect2, varscan2
- PI3 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); catalogued as COSV54782927, COSV99714172; called by muse, mutect2, varscan2
- PIWIL3 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV100177580; called by muse, mutect2, varscan2
- PLD3 | c.1245C>G p.N415K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV99396621; called by muse, mutect2, varscan2
- PTH2 | c.128+1G>T p.X43_splice | Splice Site (SNP) | VAF 20/170 reads (12%) | catalogued as rs1201545229, COSV99569565; called by muse, mutect2, varscan2
- PTPRM | c.2425A>G p.M809V | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100156854; called by muse, mutect2, varscan2
- PTPRM | c.3757C>T p.Q1253* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100156856; called by muse, mutect2, varscan2
- RECK | c.191A>T p.K64I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV100937469; called by muse, mutect2, varscan2
- SCAF1 | c.3647G>T p.R1216L | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100566909; called by muse, mutect2, varscan2
- SLC6A9 | c.503G>A p.C168Y (on ENST00000360584 / NM_201649.4; = p.C114Y on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100746194; called by muse, mutect2, varscan2
- SLC8A3 | c.190T>A p.Y64N | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as COSV100776124; called by muse, mutect2, varscan2
- SORCS2 | c.1513C>G p.L505V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV100212442; called by muse, mutect2, varscan2
- SRRM2 | c.4514T>C p.L1505P | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.384); catalogued as COSV57081617; called by muse, mutect2, varscan2
- STAP1 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1253369617, COSV55328783; called by muse, mutect2, varscan2
- TECPR2 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV100849947; called by muse, mutect2, varscan2
- TLR7 | c.2027A>G p.N676S | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV101027847; called by muse, mutect2, varscan2
- TRPM2 | c.700G>C p.G234R | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV100308692, COSV55978460; called by muse, mutect2, varscan2
- TRPM5 | c.3154G>A p.V1052I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs753713285, COSV50166785, COSV99330028; called by muse, mutect2, varscan2
- UGGT2 | c.3898C>A p.L1300I | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948652; called by muse, mutect2, varscan2
- UPK3B | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99991057; called by muse, mutect2, varscan2
- USP25 | c.2927A>T p.E976V | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV99583660; called by muse, mutect2, varscan2
- YTHDC1 | c.460-2A>G p.X154_splice | Splice Site (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100704690; called by muse, mutect2, varscan2
- ZNF536 | c.2809A>T p.K937* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100835149; called by muse, mutect2, varscan2
- ZNF790 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as COSV100764811; called by muse, mutect2, varscan2
- CERT1 | c.2047del p.C683Vfs*5 (on ENST00000405807 / NM_001130105.1; = p.C555Vfs*5 on NM_005713.3) | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- COL16A1 | c.2256del p.E753Kfs*23 | Frame Shift Del (DEL) | VAF 67/210 reads (32%) | called by mutect2, pindel, varscan2
- FASTKD1 | c.1412del p.N471Ifs*2 | Frame Shift Del (DEL) | VAF 59/257 reads (23%) | called by mutect2, pindel, varscan2
- GABRG3 | c.1085_1090del p.R362_W363del | In Frame Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- GOLGA4 | c.5083del p.K1696Sfs*11 | Frame Shift Del (DEL) | VAF 76/276 reads (28%) | called by mutect2, pindel, varscan2
- MSANTD4 | c.732_733dup p.M245Tfs*9 | Frame Shift Ins (INS) | VAF 23/89 reads (26%) | called by mutect2, pindel, varscan2
- PPP4R3B | c.1792del p.I598Lfs*22 (on ENST00000616407 / NM_001122964.3; = p.I513Lfs*22 on NM_020463.4) | Frame Shift Del (DEL) | VAF 30/145 reads (21%) | called by mutect2, pindel, varscan2
- SCAMP2 | c.674_698del p.F225Sfs*33 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- SLC16A8 | c.1132_1137del p.P378_S379del | In Frame Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- UNKL | c.1597_1598del p.V533Pfs*36 | Frame Shift Del (DEL) | VAF 56/186 reads (30%) | called by pindel, varscan2
- WIPF2 | c.1175del p.F392Sfs*14 | Frame Shift Del (DEL) | VAF 53/141 reads (38%) | called by mutect2, pindel, varscan2
- ABCD1 | c.1554G>T p.R518= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV99497514; called by muse, mutect2, varscan2
- C20orf96 | c.66T>A p.V22= (on ENST00000360321 / NM_153269.3; = p.V21= on NM_080571.1) | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as COSV100826708; called by muse, mutect2, varscan2
- CHD8 | c.2892C>G p.L964= (on ENST00000646647 / NM_001170629.2; = p.L685= on NM_020920.4) | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV101303008, COSV101303136; called by muse, mutect2, varscan2
- CLDN6 | c.594C>T p.A198= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV100172148; called by muse, mutect2, varscan2
- CSF3R | c.240T>C p.D80= | Silent (SNP) | VAF 62/262 reads (24%) | catalogued as COSV100117647; called by muse, varscan2
- DDX54 | c.1755G>C p.L585= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs778341954, COSV100013826; called by muse, mutect2, varscan2
- DGKQ | c.1377G>A p.T459= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs373354724; called by muse, mutect2, varscan2
- DYRK3 | c.694C>A p.R232= | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as COSV100895676, COSV65605261; called by muse, mutect2, varscan2
- HSPA12A | c.1557C>T p.V519= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as rs782035745, COSV100979783; called by muse, mutect2, varscan2
- IGHD4-4 | c.9G>A p.Q3= | Silent (SNP) | VAF 63/208 reads (30%) | called by muse, mutect2, varscan2
- KIF5A | c.1803G>T p.V601= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as COSV99672869; called by muse, mutect2, varscan2
- PAFAH1B3 | c.303G>A p.V101= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs755491991, COSV99359462; called by muse, mutect2, varscan2
- PDCD6IP | c.1755G>A p.L585= | Silent (SNP) | VAF 88/366 reads (24%) | catalogued as COSV100218756; called by muse, mutect2, varscan2
- PLXNA1 | c.4839C>G p.S1613= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as COSV99302901; called by muse, mutect2, varscan2
- PTOV1 | c.384C>T p.G128= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs149977568; called by muse, mutect2, varscan2
- RRP1B | c.1785G>A p.K595= | Silent (SNP) | VAF 56/182 reads (31%) | catalogued as COSV100512995; called by muse, mutect2, varscan2
- UPP1 | c.570G>C p.L190= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs567267997, COSV100080670; called by muse, mutect2, varscan2
- UQCRC2 | c.495C>T p.A165= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as COSV99193304; called by muse, mutect2, varscan2
- ZNF468 | c.909A>G p.E303= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs1295488181, COSV54695881; called by muse, mutect2, varscan2
- CHCHD2P9 | n.236C>A | RNA (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
